Gene-level copy-number profile of tumor specimen TCGA-61-1743-01A from TCGA case TCGA-61-1743, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 53.0 years (19,365 days).
Specimen TCGA-61-1743-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.fb06147a-5892-4f9f-9698-4d71896fa8e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1743-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/291d3082-441d-448c-9069-680b7fffa4dd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 10,064; copy number 2: 20,489; copy number 3: 24,103; copy number 4: 3,894; copy number 5: 670; copy number 6: 32; copy number 7: 101; copy number 8: 90; copy number 9: 1; copy number 10: 5; copy number 12: 65; copy number 13: 83; copy number 14: 31; copy number 15: 16; copy number 27: 35; copy number 29: 8; copy number 32: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-61-1743-01): tumor purity 0.86, ploidy 5.55, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:47,630,827–48,023,004, 1 gene (within-gene range 0–1): AL117329.1.
- chr22:47,916,728–50,801,309, 96 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 463 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:53,766,400–53,766,614, 1 gene, copy number 9: AL365496.1.
- chr11:73,157,946–80,762,826, 191 genes, copy number 7–27 (broad region; genes not listed).
- chr15:38,628,005–40,076,539, 24 genes, copy number 15–29 (within-gene range 2–29): LINC02694, AC022929.1, AC022929.2, AC013652.1, AC087878.1, AC113146.1, C15orf54, AC013652.2, AC109630.1, AC022196.1, THBS1, AC037198.1, AC037198.2, FSIP1, AC023908.2, AC023908.3, GPR176, AC023908.1, GPR176-DT, Y_RNA, EIF2AK4, H3P38, SRP14, SRP14-AS1.
- chr17:39,603,536–40,100,589, 28 genes, copy number 32: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1.
- chr22:24,594,811–24,629,005, 1 gene, copy number 7 (within-gene range 2–7): GGT1.
- chr22:24,632,915–25,564,719, 39 genes, copy number 7: BCRP3, AP000356.4, AP000356.3, AP000356.2, POM121L10P, ARL5AP4, AP000357.1, AP000357.2, AP000358.1, CRIP1P4, PIWIL3, SGSM1, AL049759.1, TMEM211, KIAA1671, AL022323.2, AL022323.4, AL022323.1, AL022323.3, KIAA1671-AS1, Z99916.2, CRYBB3, Z99916.1, CRYBB2, Z99916.3, AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1.
- chr22:25,580,241–25,581,382, 1 gene, copy number 7: AL022329.2.
- chr22:26,161,834–27,061,247, 33 genes, copy number 8: LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2.
- chr22:27,676,559–27,920,134, 5 genes, copy number 10 (within-gene range 2–10): AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB.
- chr22:29,705,256–33,058,381, 140 genes, copy number 8–13 (within-gene range 2–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
